Somatic mutation profile of tumor specimen TCGA-61-2016-01A (aliquot TCGA-61-2016-01A-01W-0722-08) from TCGA case TCGA-61-2016, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.4 years (18,788 days).
Specimen TCGA-61-2016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67af0e3f-f2da-4884-94c8-fb251445f53a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2016-10A (Blood Derived Normal), aliquot TCGA-61-2016-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7f98034-f711-4aa8-8675-6383f75e19e8

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 284/648 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2303G>T p.R768M | Missense Mutation (SNP) | VAF 169/226 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV52221730; called by muse, mutect2, varscan2
- CCDC17 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV59647032; called by muse, varscan2
- CHD8 | c.6940C>T p.R2314W (on ENST00000646647 / NM_001170629.2; = p.R2035W on NM_020920.4) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs371169926; called by muse, mutect2
- COQ10A | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as COSV57524629; called by muse, mutect2, varscan2
- CWH43 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 111/152 reads (73%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as COSV56938684; called by muse, mutect2, varscan2
- DCAF6 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 18/251 reads (7%) | catalogued as COSV100393976, COSV100394645; called by muse, mutect2
- DGKI | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 164/409 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773058095, COSV55949015, COSV99937841, COSV99938434; called by muse, mutect2, varscan2
- DOCK7 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV52004429; called by muse, mutect2
- FAT3 | c.5283T>A p.D1761E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53107125; called by muse, mutect2, varscan2
- MACO1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV65476383; called by muse, mutect2, varscan2
- MAGEC1 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 131/735 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.258); catalogued as COSV53574282, COSV99594941; called by muse, mutect2, varscan2
- MOAP1 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV52092522; called by muse, mutect2, varscan2
- MYH15 | c.5084C>G p.S1695C | Missense Mutation (SNP) | VAF 15/577 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99842381; called by muse, mutect2
- OR2A4 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs1331272204, COSV59575872; called by muse, mutect2, varscan2
- OR2M7 | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV100522432; called by muse, mutect2
- SALL1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 188/495 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1259775353, COSV51752892, COSV51755004; called by muse, mutect2, varscan2
- SCML4 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV64635502; called by muse, mutect2, varscan2
- SEMA3D | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs754320615, COSV52399569, COSV99405932; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 43/63 reads (68%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- XCL2 | c.90G>C p.R30S | Missense Mutation (SNP) | VAF 126/407 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63194298; called by muse, mutect2, varscan2
- ZNF804B | c.2106G>C p.Q702H | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60826481, COSV60832560; called by muse, mutect2, varscan2
- CATSPER4 | c.1275G>A p.T425= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as rs1001393617, COSV58793073, COSV58795020; called by muse, mutect2, varscan2
- KCNG1 | c.555G>A p.E185= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV65368436; called by muse, mutect2
- SCNN1B | c.1725G>C p.P575= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV56304061; called by muse, mutect2, varscan2
- SGIP1 | c.1407A>T p.P469= | Silent (SNP) | VAF 56/638 reads (9%) | catalogued as COSV52768042; called by muse, mutect2
- TRPV6 | c.2040C>T p.N680= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV63891702; called by muse, mutect2, varscan2
